Somatic mutation profile of tumor specimen HCM-CSHL-0868-C56-06A (aliquot HCM-CSHL-0868-C56-06A-11D-A881-36) from HCMI case HCM-CSHL-0868-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIB; FIGO stage: Stage IIIB; Tumor grade: High Grade; Age at diagnosis: 62.3 years (22,759 days).
Specimen HCM-CSHL-0868-C56-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec765ef2-9c60-4b2f-8c90-d4180e36e05a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0868-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0868-C56-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f404b1de-8fa2-483e-ab9c-db759b7c4c65

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Nonsense Mutation 2, 5'UTR 2, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 40/258 reads (16%) | catalogued as rs786201592, COSV52735606, COSV52751148, COSV52783951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CSNK1G3 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1377658128; called by muse, mutect2, varscan2
- DOK2 | c.652G>C p.V218L | Missense Mutation (SNP) | VAF 49/306 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV52390764; called by muse, mutect2, varscan2
- FRMPD3 | c.4211C>T p.S1404L | Missense Mutation (SNP) | VAF 99/853 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs755437325, COSV52196755; called by muse, mutect2, varscan2
- IQCB1 | c.1367T>C p.V456A | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs1456257526; called by mutect2, varscan2
- KCNA2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 77/459 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV60368676; called by muse, mutect2, varscan2
- NTM | c.578G>T p.R193M | Missense Mutation (SNP) | VAF 73/386 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100868674, COSV66178113; called by muse, mutect2, varscan2
- OTOL1 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 85/543 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs758208110, COSV60007131; called by muse, mutect2, varscan2
- SHANK1 | c.6071C>T p.P2024L | Missense Mutation (SNP) | VAF 99/675 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs865824347; called by muse, mutect2, varscan2
- SLCO2B1 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 69/396 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs752102813; called by muse, mutect2, varscan2
- SSBP3 | c.526G>A p.G176R (on ENST00000371320 / NM_145716.4; = p.G156R on NM_018070.5) | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100486455; called by muse, mutect2, varscan2
- STUM | c.215C>A p.S72* | Nonsense Mutation (SNP) | VAF 54/444 reads (12%) | catalogued as rs1244169469, COSV64684422; called by muse, mutect2, varscan2
- TNK2 | c.2851G>A p.D951N | Missense Mutation (SNP) | VAF 168/519 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as rs764262169, COSV57373752; called by muse, mutect2, varscan2
- TSSK1B | c.256G>C p.V86L | Missense Mutation (SNP) | VAF 69/398 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV101180895; called by muse, mutect2, varscan2
- ZNF408 | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.292); catalogued as rs940672700; called by muse, mutect2, varscan2
- ACY3 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 91/551 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- AFMID | c.565G>C p.G189R | Missense Mutation (SNP) | VAF 162/362 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CSMD1 | c.3494A>G p.D1165G (on ENST00000520002; = p.D1164G on NM_033225.6) | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTTNBP2 | c.901G>T p.V301L | Missense Mutation (SNP) | VAF 75/312 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHRS1 | c.683C>A p.T228N | Missense Mutation (SNP) | VAF 66/430 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2
- DNAH17 | c.11618C>A p.T3873K | Missense Mutation (SNP) | VAF 67/443 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- EGFLAM | c.518T>A p.I173N | Missense Mutation (SNP) | VAF 23/344 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ELSPBP1 | c.402C>G p.I134M | Missense Mutation (SNP) | VAF 76/347 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- GPR152 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 77/487 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HTR4 | c.1132T>C p.S378P | Missense Mutation (SNP) | VAF 75/423 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- MARK4 | c.1832C>G p.P611R | Missense Mutation (SNP) | VAF 114/513 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MST1 | c.148C>G p.H50D | Missense Mutation (SNP) | VAF 148/428 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.234); called by mutect2, varscan2
- NCKAP5 | c.4888G>C p.A1630P | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- NOVA2 | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 50/397 reads (13%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- NYAP2 | c.123_136del p.D41Efs*2 | Frame Shift Del (DEL) | VAF 39/297 reads (13%) | called by mutect2, pindel, varscan2
- PCDHGA2 | c.1738C>A p.R580S | Missense Mutation (SNP) | VAF 17/633 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- PHKA1 | c.1289T>A p.F430Y | Missense Mutation (SNP) | VAF 70/503 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- PLEKHG5 | c.1705C>G p.R569G (on ENST00000400915 / NM_001042663.3; = p.R532G on NM_020631.6) | Missense Mutation (SNP) | VAF 122/717 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- PPP1R8 | c.888C>G p.N296K (on ENST00000311772 / NM_014110.5; = p.N72K on NM_002713.4) | Missense Mutation (SNP) | VAF 119/601 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RBM15B | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 82/395 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- REN | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 55/379 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- SBNO2 | c.3602G>C p.R1201T | Missense Mutation (SNP) | VAF 98/439 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SPEG | c.9383T>A p.M3128K | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by mutect2, varscan2
- TENM2 | c.7474A>G p.N2492D (on ENST00000518659 / NM_001122679.2; = p.N2253D on NM_001080428.3) | Missense Mutation (SNP) | VAF 55/325 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM219 | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 59/342 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- YIPF6 | c.309-1G>C p.X103_splice | Splice Site (SNP) | VAF 57/305 reads (19%) | called by muse, mutect2, varscan2
- ZNF335 | c.1917C>A p.H639Q | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPNE3 | c.246C>T p.I82= | Silent (SNP) | VAF 101/380 reads (27%) | catalogued as rs770032983; called by muse, mutect2, varscan2
- FAM83H | c.3195C>T p.T1065= | Silent (SNP) | VAF 248/831 reads (30%) | called by muse, varscan2
- FMN2 | c.4365G>T p.L1455= | Silent (SNP) | VAF 59/382 reads (15%) | called by muse, mutect2, varscan2
- FUT4 | c.96G>C p.S32= | Silent (SNP) | VAF 103/676 reads (15%) | catalogued as rs761018933, COSV100707960; called by muse, mutect2, varscan2
- KIF3B | c.297G>T p.G99= | Silent (SNP) | VAF 39/270 reads (14%) | called by muse, mutect2, varscan2
- MYT1L | c.2385C>G p.S795= | Silent (SNP) | VAF 141/518 reads (27%) | catalogued as COSV101219092; called by muse, mutect2, varscan2
- SMIM10L2A | c.148C>T p.L50= | Silent (SNP) | VAF 67/415 reads (16%) | called by muse, mutect2, varscan2
- STUM | c.423G>T p.L141= | Silent (SNP) | VAF 101/417 reads (24%) | called by muse, mutect2, varscan2
- TBC1D2B | c.1254G>A p.E418= | Silent (SNP) | VAF 68/347 reads (20%) | called by muse, mutect2, varscan2
- ZNF121 | c.657A>T p.V219= | Silent (SNP) | VAF 68/367 reads (19%) | called by muse, mutect2, varscan2
- BAD | c.188-5173G>A | Intron (SNP) | VAF 61/428 reads (14%) | catalogued as rs551978698; called by muse, mutect2, varscan2
- IMPA1 | c.-4G>A | 5'UTR (SNP) | VAF 113/421 reads (27%) | catalogued as rs465178; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.-312G>T | 5'UTR (SNP) | VAF 249/919 reads (27%) | called by muse, mutect2, varscan2
